Somatic mutation profile of tumor specimen MP2PRT-PAVMPY-TMP1-A (aliquot MP2PRT-PAVMPY-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVMPY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (946 days).
Specimen MP2PRT-PAVMPY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05c44752-e5ec-4422-b0bf-8caf9bb6a0ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVMPY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVMPY-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a49a568-b975-4403-911b-5baa8f5fd211

The open-access MAF lists 111 somatic variants for this specimen: 84 protein-altering or splice-affecting, 20 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 20, Nonsense Mutation 7, Intron 3, IGR 1, Splice Region 1, 5'Flank 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.2513G>A p.R838Q | Missense Mutation (SNP) | VAF 122/338 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1458936301; called by muse, mutect2, varscan2
- C1QL4 | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 116/288 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as rs1446716271; called by muse, mutect2, varscan2
- C1QL4 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 262/686 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1004099614; called by muse, mutect2, varscan2
- DNAH11 | c.1949C>G p.S650* | Nonsense Mutation (SNP) | VAF 55/227 reads (24%) | catalogued as rs755002843, COSV100178044; called by muse, mutect2, varscan2
- DNAH11 | c.5141T>C p.V1714A | Missense Mutation (SNP) | VAF 31/319 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs775475984; called by muse, mutect2, varscan2
- EGFL8 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 285/677 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs1382909455, COSV61248021; called by muse, mutect2, varscan2
- FAM20A | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 186/482 reads (39%) | catalogued as COSV73980954; called by muse, mutect2, varscan2
- FSTL4 | c.1341C>G p.G447= | Splice Region (SNP) | VAF 95/297 reads (32%) | catalogued as COSV54781167; called by muse, mutect2, varscan2
- LRRC3 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 257/613 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs761564942, COSV99381830; called by muse, mutect2, varscan2
- MAGI3 | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 132/340 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as rs771030659, COSV56833179; called by muse, mutect2, varscan2
- MASTL | c.2425C>G p.Q809E (on ENST00000375940 / NM_001372029.1; = p.Q808E on NM_032844.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV60910526; called by muse, mutect2, varscan2
- MED12 | c.2125G>C p.E709Q | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.734); catalogued as COSV61356733; called by muse, mutect2
- MYO3A | c.2747G>C p.R916T | Missense Mutation (SNP) | VAF 35/401 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.395); catalogued as rs1200402861; called by muse, mutect2
- NAV2 | c.3883C>G p.P1295A (on ENST00000396087 / NM_001244963.2; = p.P1272A on NM_145117.5) | Missense Mutation (SNP) | VAF 131/355 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.323); catalogued as rs1038338459; called by muse, mutect2, varscan2
- NID2 | c.3682C>G p.L1228V | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1408591273, COSV99356517; called by muse, mutect2
- NLRP4 | c.2077C>G p.Q693E | Missense Mutation (SNP) | VAF 89/408 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV56709149; called by muse, mutect2, varscan2
- NOD2 | c.1618C>T p.L540F | Missense Mutation (SNP) | VAF 217/521 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.344); catalogued as COSV56049549, COSV56052749; called by muse, mutect2, varscan2
- NOX5 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 320/445 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as rs866041515; called by muse, mutect2, varscan2
- PCDHB7 | c.612G>C p.E204D | Missense Mutation (SNP) | VAF 146/314 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as COSV50755655; called by muse, mutect2, varscan2
- PELP1 | c.2090C>T p.S697L | Missense Mutation (SNP) | VAF 258/664 reads (39%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.022); catalogued as rs558960670, COSV52585752; called by muse, mutect2, varscan2
- PMAIP1 | c.82C>G p.Q28E | Missense Mutation (SNP) | VAF 125/334 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV54054356; called by muse, mutect2, varscan2
- PUF60 | c.684C>G p.I228M (on ENST00000526683 / NM_001362896.2; = p.I211M on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 283/713 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57590314; called by muse, mutect2, varscan2
- RSF1 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 108/298 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV57839504; called by muse, mutect2, varscan2
- SPATA7 | c.900G>T p.M300I | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV99061151; called by muse, mutect2, varscan2
- TAS2R3 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 178/440 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as COSV56091994; called by muse, mutect2, varscan2
- THEMIS | c.1814C>G p.S605* | Nonsense Mutation (SNP) | VAF 152/398 reads (38%) | catalogued as COSV64070729; called by muse, mutect2, varscan2
- ZHX2 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 140/364 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs898550597; called by muse, mutect2, varscan2
- ZNF324 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 153/409 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.1); catalogued as COSV52180577, COSV52181288; called by muse, mutect2, varscan2
- ZNF333 | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 162/399 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs769092527; called by muse, mutect2, varscan2
- ZP4 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 132/376 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs766375009, COSV63912557; called by muse, mutect2, varscan2
- ADAMTS5 | c.2710G>C p.D904H | Missense Mutation (SNP) | VAF 81/368 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ADCY8 | c.2448G>C p.K816N | Missense Mutation (SNP) | VAF 39/283 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AMELY | c.182G>A p.R61K (on ENST00000383036 / NM_001364814.1; = p.R47K on NM_001143.1) | Missense Mutation (SNP) | VAF 71/96 reads (74%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ANKRD62 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- ATP2B1 | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AURKB | c.504G>C p.K168N | Missense Mutation (SNP) | VAF 125/299 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CCS | c.67C>G p.Q23E | Missense Mutation (SNP) | VAF 177/456 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CELA3A | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 94/347 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHGA | c.664G>C p.G222R | Missense Mutation (SNP) | VAF 116/680 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, varscan2
- CLTC | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CPXM2 | c.545G>C p.G182A | Missense Mutation (SNP) | VAF 133/531 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- DDX56 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 135/349 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- EVA1B | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 106/613 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EYS | c.2869G>C p.E957Q | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2
- FAM124A | c.103G>C p.E35Q (on ENST00000322475 / NM_001242312.2; = p.E71Q on NM_145019.4) | Missense Mutation (SNP) | VAF 108/162 reads (67%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- FLOT1 | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 296/724 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- FSIP2 | c.19183A>T p.R6395* | Nonsense Mutation (SNP) | VAF 77/207 reads (37%) | called by muse, mutect2, varscan2
- HMGCR | c.2584C>G p.L862V | Missense Mutation (SNP) | VAF 144/354 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- IGKV2D-24 | chr2:90005627 CCTCACACAGTGGTA>TTAGCCCTCCGGGT | Missense Mutation (DEL) | VAF 64/84 reads (76%) | called by pindel, varscan2*
- ITGA5 | c.1754G>A p.R585K | Missense Mutation (SNP) | VAF 126/367 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1174G>C p.D392H | Missense Mutation (SNP) | VAF 137/187 reads (73%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- JPH2 | c.1426G>C p.E476Q | Missense Mutation (SNP) | VAF 32/922 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.025); called by muse, mutect2
- KCNH2 | c.2876C>G p.S959C | Missense Mutation (SNP) | VAF 42/899 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.237); called by muse, mutect2
- KCTD20 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 181/443 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MAGEB16 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 66/252 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- MED23 | c.2542G>C p.E848Q | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.114); called by muse, mutect2
- MKNK2 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 113/285 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MOK | c.683A>T p.K228M | Missense Mutation (SNP) | VAF 95/249 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- MYH8 | c.2947G>C p.E983Q | Missense Mutation (SNP) | VAF 88/195 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- NODAL | c.374C>G p.S125* | Nonsense Mutation (SNP) | VAF 151/580 reads (26%) | called by muse, mutect2, varscan2
- NXPE1 | c.1614G>C p.Q538H (on ENST00000424269; = p.Q396H on NM_152315.5) | Missense Mutation (SNP) | VAF 77/294 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OBSL1 | c.2572G>T p.E858* | Nonsense Mutation (SNP) | VAF 40/828 reads (5%) | called by muse, mutect2
- PAFAH1B2 | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 39/330 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- PCDHGA7 | c.1087G>C p.G363R | Missense Mutation (SNP) | VAF 88/255 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PKD1L3 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 144/360 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PLPP4 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 190/677 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PNMA8B | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 81/548 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- PPEF1 | c.1191G>C p.K397N | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- RAB31 | c.527G>C p.G176A | Missense Mutation (SNP) | VAF 16/406 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.186); called by muse, mutect2
- RBBP5 | c.987G>C p.W329C | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SEMA5A | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 113/305 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SERAC1 | c.994C>G p.H332D | Missense Mutation (SNP) | VAF 17/261 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SERINC4 | c.1343G>C p.S448T | Missense Mutation (SNP) | VAF 80/103 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- SHANK1 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 21/705 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, mutect2
- SIRT3 | c.94C>G p.Q32E | Missense Mutation (SNP) | VAF 308/766 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SPNS3 | c.1076C>G p.A359G | Missense Mutation (SNP) | VAF 213/522 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SPRYD3 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 202/467 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- TAF1B | c.1098G>C p.L366F | Missense Mutation (SNP) | VAF 87/216 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TASOR | c.3310C>T p.Q1104* (on ENST00000355628 / NM_001365636.2; = p.Q728* on NM_015224.3) | Nonsense Mutation (SNP) | VAF 128/370 reads (35%) | called by muse, mutect2, varscan2
- TCAIM | c.554G>C p.R185T | Missense Mutation (SNP) | VAF 77/182 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- WRNIP1 | c.660G>C p.Q220H | Missense Mutation (SNP) | VAF 376/898 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); called by muse, mutect2
- ZNF236 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 60/241 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- ZNF57 | c.556C>G p.H186D | Missense Mutation (SNP) | VAF 97/245 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- ZNF749 | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 26/334 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2
- ACSM6 | c.831C>T p.S277= | Silent (SNP) | VAF 284/548 reads (52%) | catalogued as rs146080729; called by muse, mutect2, varscan2
- CCNH | c.546G>A p.E182= | Silent (SNP) | VAF 57/281 reads (20%) | called by muse, mutect2, varscan2
- CCR10 | c.735G>T p.A245= | Silent (SNP) | VAF 274/662 reads (41%) | called by muse, mutect2, varscan2
- COL28A1 | c.2082G>A p.Q694= | Silent (SNP) | VAF 14/380 reads (4%) | called by muse, mutect2
- DHDDS | c.402G>C p.L134= | Silent (SNP) | VAF 94/246 reads (38%) | called by muse, mutect2, varscan2
- EIPR1 | c.1143G>A p.L381= | Silent (SNP) | VAF 83/299 reads (28%) | catalogued as rs535560748; called by muse, mutect2, varscan2
- GINS4 | c.519G>C p.L173= | Silent (SNP) | VAF 98/249 reads (39%) | called by muse, mutect2, varscan2
- INTS1 | c.5535C>G p.L1845= | Silent (SNP) | VAF 251/599 reads (42%) | catalogued as rs1265170626; called by muse, mutect2, varscan2
- INTS7 | c.903G>A p.Q301= | Silent (SNP) | VAF 77/195 reads (39%) | catalogued as COSV65343659; called by muse, mutect2, varscan2
- KIFC1 | c.312G>A p.K104= | Silent (SNP) | VAF 58/481 reads (12%) | called by muse, mutect2, varscan2
- MAGEB1 | c.732C>T p.F244= | Silent (SNP) | VAF 218/268 reads (81%) | called by muse, mutect2, varscan2
- NXPH4 | c.624C>T p.L208= | Silent (SNP) | VAF 195/531 reads (37%) | catalogued as rs1435622574; called by muse, mutect2, varscan2
- PCF11 | c.483G>C p.V161= | Silent (SNP) | VAF 103/220 reads (47%) | catalogued as COSV53536068; called by muse, mutect2, varscan2
- PPP1R1C | c.123C>G p.L41= | Silent (SNP) | VAF 80/217 reads (37%) | catalogued as COSV99724418; called by muse, mutect2, varscan2
- PRDM13 | c.2064C>G p.V688= | Silent (SNP) | VAF 201/740 reads (27%) | called by muse, mutect2, varscan2
- RTN4RL2 | c.678C>A p.L226= | Silent (SNP) | VAF 84/701 reads (12%) | catalogued as rs1270875134, COSV58651794; called by muse, mutect2, varscan2
- SPTBN1 | c.1029A>G p.A343= | Silent (SNP) | VAF 28/444 reads (6%) | called by muse, mutect2
- SUPT5H | c.1647C>T p.V549= | Silent (SNP) | VAF 166/403 reads (41%) | called by muse, mutect2, varscan2
- TRIM77 | c.273G>A p.L91= | Silent (SNP) | VAF 62/495 reads (13%) | called by muse, mutect2
- ZNF728 | c.1383C>T p.F461= | Silent (SNP) | VAF 72/360 reads (20%) | called by muse, mutect2
- CNTN1 | c.1805-9423C>T | Intron (SNP) | VAF 109/291 reads (37%) | catalogued as rs779041716, COSV100751765; called by muse, mutect2, varscan2
- CRYAA | c.189+557G>C | Intron (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2
- GNAO1 | c.723+4118G>C | Intron (SNP) | VAF 18/242 reads (7%) | called by muse, mutect2
- HEXIM1 | c.-576G>C | 5'UTR (SNP) | VAF 17/513 reads (3%) | called by muse, mutect2
- PRF1 | c.*267C>T | 3'UTR (SNP) | VAF 268/469 reads (57%) | called by muse, mutect2, varscan2
- TRGV3 | chr7:38362863 ins GCCCGA | 5'Flank (INS) | VAF 50/109 reads (46%) | called by mutect2, pindel, varscan2
- Unknown | chr4:128428259 C>G | IGR (SNP) | VAF 47/388 reads (12%) | called by muse, mutect2
